Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87D, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87D-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-O-3

Adenocarcinoma, acinar
8140/3

Site: Prostate NOS
C61.9

QAS 11/21/13

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Gender: M

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Physician(s):

DIAGNOSIS:

PROSTATE, LAPAROSCOPIC RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON GRADE 4 + 5 = SCORE OF 9, INVOLVING APPROXIMATELY 30% OF SAMPLED TISSUE AND PRESENT IN ALL FOUR QUADRANTS (SEE SYNOPSIS)
- EXTENSIVE PERINEURAL INVASION IDENTIFIED
- EXTRAPROSTATIC EXTENSION IDENTIFIED IN THE RIGHT BASE AND APEX
- TUMOR IS PRESENT AT MARGIN IN THE RIGHT APEX AND BASE

SEMINAL VESICLES, BILATERAL, LAPAROSCOPIC RADICAL PROSTATECTOMY

- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, LEFT PELVIC, DISSECTION

- METASTATIC ADENOCARCINOMA IN THREE OF SIX LYMPH NODES (3/6)
- EXTRACAPSULAR EXTENSION IDENTIFIED

LYMPH NODES, RIGHT PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN NINE LYMPH NODES (0/9)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Called to pick up 'prostate,' consisting of a 34 gram prostate measuring 3 x 3 x 3 cm with attached seminal vesicles measuring 2 x 1 x 1 cm on the right and 4 x 1 x 1 cm on the left. Inked black. Tissue taken for tumor bank. Rest for permanents," by

[page 2 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old man with a prostate specific antigen of 10 and clinical stage T2 Gleason score 8 adenocarcinoma with weakly PET+/abnormal left pelvic lymph nodes. Operative procedure: Laparoscopic radical prostatectomy.

Specimen(s) Received:

A: LYMPH NODE, RIGHT PELVIC
B: LYMPH NODE, LEFT PELVIC
C: PROSTATE

Gross Description:

The specimens are received in three formalin-filled containers, each labeled [REDACTED]. The first container is labeled "right pelvic lymph node." It contains a 6 x 5 x 1.5 cm aggregate of fibrofatty tissue dissected to show multiple lymph nodes. Labeled A1 to A3, two lymph nodes each; A4 and A5, a single lymph node bisected. Jar 1.

The second container is labeled "left pelvic lymph nodes." It contains a 6 x 5.5 x 2.5 cm aggregate of fibrofatty tissue. Dissected to show multiple lymph nodes. Labeled B1 to B3, a single lymph node each; B4 and B5, a single lymph node. Bisected. Jar 1.

The third container is labeled "prostate." It contains a 33 gram prostate with a defect in the left lobe measuring 2 x 0.5 x 1 cm and in the right lobe measuring 2 x 0.5 x 1 cm where tissue has been taken for tumor bank. The prostate measures 3 x 3 x 3.5 cm and the left seminal vesicle measures 2.5 x 1 x 0.6 cm and the right measures 4 x 1 x 1 cm. The prostate is sectioned to show a whorled, nodular cut surface. Labeled C1, shave bladder resection margin; C2 and C3, left and right aspects of apical margin, respectively; C4 and C5, left base; C6 and C7, left apex; C8 and C9, right base; C10 and C11, right apex; C12, left seminal vesicle; C13, right seminal vesicle. Jar 1.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

[page 3 of 5]
Patient Name: [REDACTED]

[REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 30%

GLEASON'S GRADE

The Gleason's Grade is 4+5

TUMOR LOCATION

The location of the tumor involves the

right base

right apex

left base

left apex

PERINEURAL INVASION

Perineural invasion is identified

VASCULAR INVASION

Vascular invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is present

Extraprostatic (extracapsular) extension is focal (less than or equal to two 400x fields)

The tumor extends into the periprostatic soft tissues (specify site): In the right apex and base

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

Tumor is present at sampled peripheral margin of resection in the (specify site) right apex and right base, with extra prostatic extension

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Right pelvic: 0/9

Left pelvic: 3/6

Extranodal extension by tumor metastases is present

PRIMARY TUMOR (T)

Extracapsular extension (unilateral or bilateral) (T3a)

REGIONAL LYMPH NODES (N)

Metastasis in regional lymph node(s) (N1)

DISTANT METASTASIS

No distant metastasis is reportedly present (M0)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T3/N1/M0 (Stage IV)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 4 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Surgical Pathology report is available on-line at:

END OF REPORT

Page 4 of 4

Disenfranchisement		✓

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS):

TSS Identifier:

TSS Unique Patient Identifier:

Completed By (Interviewer Name on OpenClinica):

Completed Date:

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is $4+5=9$	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is $4+3=7$	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 857f9bff-9032-451b-aaa9-0744d86463f5 (TCGA-VP-A87D.48B36158-9679-4C74-BBDA-88431481A885.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).